Somatic mutation profile of tumor specimen TCGA-CV-7263-01A (aliquot TCGA-CV-7263-01A-11D-2012-08) from TCGA case TCGA-CV-7263, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 64.4 years (23,513 days).
Specimen TCGA-CV-7263-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b5877b8-405e-4ecb-997a-71e65280cb59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7263-10A (Blood Derived Normal), aliquot TCGA-CV-7263-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a94c0ac0-7cef-4205-b07d-fafe703a01db

The open-access MAF lists 114 somatic variants for this specimen: 91 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 19, Nonsense Mutation 5, Intron 3, Frame Shift Del 3, Splice Site 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PYGM | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377225525, CM076447; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGPS | c.1816A>G p.I606V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV51561417, COSV99931138; called by muse, mutect2, varscan2
- AK5 | c.782A>G p.Q261R (on ENST00000354567 / NM_174858.3; = p.Q235R on NM_012093.4) | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV100642435; called by muse, mutect2, varscan2
- ALPG | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377699892; called by muse, mutect2, varscan2
- ANO4 | c.55G>A p.E19K (on ENST00000392977 / NM_001286615.2; = p.V19M on NM_178826.4) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.678); catalogued as COSV100152324, COSV100153039; called by muse, mutect2, varscan2
- BMP2 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV101122062; called by muse, mutect2
- CSPG5 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99273690; called by muse, mutect2, varscan2
- CYP4B1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV54726530; called by muse, mutect2, varscan2
- DNAH5 | c.6911G>A p.R2304Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs558294959, COSV54235852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP6 | c.384G>T p.K128N (on ENST00000377770 / NM_001364500.2; = p.K66N on NM_001936.5) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV100123884; called by muse, mutect2, varscan2
- DPP6 | c.946G>A p.A316T (on ENST00000377770 / NM_001364500.2; = p.A254T on NM_001936.5) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1209164860, COSV100123888, COSV59635442; called by muse, mutect2, varscan2
- DTX1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99986257; called by muse, varscan2
- DUSP29 | c.571A>C p.K191Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV100633254; called by muse, mutect2, varscan2
- ENOSF1 | c.964T>G p.W322G (on ENST00000340116 / NM_001354066.2; = p.W274G on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99200991; called by muse, mutect2, varscan2
- EVI5L | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs778590587, COSV54485629; called by muse, mutect2, varscan2
- FAT1 | c.6895G>T p.G2299* | Nonsense Mutation (SNP) | VAF 83/138 reads (60%) | catalogued as COSV101499162; called by muse, mutect2, varscan2
- FBXL13 | c.2089T>C p.F697L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100501296; called by muse, mutect2
- GAS2L2 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.76); catalogued as rs782327875; called by muse, mutect2, varscan2
- GFRA1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.916); catalogued as COSV100815573; called by muse, mutect2, varscan2
- GIPC1 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100600032; called by muse, mutect2, varscan2
- GPBP1L1 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51967062, COSV99322025; called by muse, mutect2, varscan2
- GPBP1L1 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99322028; called by muse, mutect2, varscan2
- GTF3C1 | c.791T>A p.V264D | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.048); catalogued as COSV100649106; called by muse, mutect2, varscan2
- H3C11 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV100137770; called by muse, mutect2, varscan2
- H4C2 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99774846; called by muse, mutect2
- HOXA11 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV99135898; called by muse, mutect2, varscan2
- IDO1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); catalogued as rs200244502; called by muse, mutect2, varscan2
- KAT6B | c.3670A>G p.M1224V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV99767576; called by muse, mutect2, varscan2
- KIF5C | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331505548, COSV101276107; called by muse, mutect2, varscan2
- KRT39 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100842173, COSV62917211; called by muse, mutect2, varscan2
- LAMA1 | c.8092C>T p.P2698S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV67539017; called by muse, mutect2, varscan2
- LAMC1 | c.4360G>A p.V1454I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs759507311, COSV99279227; called by muse, mutect2, varscan2
- LCT | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1017501359, COSV51555251, COSV99928905; called by muse, mutect2, varscan2
- LRRC6 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as rs1421807075, COSV99137827; called by muse, mutect2, varscan2
- MAGEB10 | c.446T>A p.F149Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1367089158, COSV100775201; called by muse, mutect2, varscan2
- MAPK13 | c.971T>C p.F324S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs764018811, COSV52983170; called by muse, mutect2, varscan2
- MBL2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV100906280; called by muse, mutect2, varscan2
- MCCC2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100040024; called by muse, mutect2, varscan2
- MGP | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99967094; called by muse, mutect2, varscan2
- MUC5B | c.14528G>A p.G4843E | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV101500118; called by muse, mutect2, varscan2
- MYH10 | c.3878C>T p.S1293F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs775866479, COSV99344513; called by muse, mutect2, varscan2
- MYO10 | c.4096G>A p.A1366T | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99944906; called by muse, mutect2, varscan2
- NDUFS1 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as COSV99260617; called by muse, mutect2, varscan2
- NFX1 | c.81T>A p.N27K | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs775981113, COSV100581920; called by muse, mutect2, varscan2
- NHLRC4 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99215861; called by muse, mutect2, varscan2
- NR2E1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1426067404, COSV100934400; called by muse, mutect2, varscan2
- NRXN1 | c.4315C>T p.R1439* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as rs1331703447, COSV60528047; called by muse, mutect2, varscan2
- NUP88 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as COSV99336412; called by muse, mutect2, varscan2
- PCLO | c.4603T>C p.S1535P | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100429054; called by muse, mutect2
- PCSK7 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs1387376063, COSV100309255; called by muse, mutect2, varscan2
- PDE3A | c.1695A>T p.L565F | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100761932; called by muse, mutect2, varscan2
- PDZD8 | c.3000G>T p.K1000N | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100041433; called by muse, mutect2, varscan2
- PHLDB2 | c.3275T>A p.I1092K (on ENST00000393925 / NM_001134439.2; = p.I1049K on NM_145753.2) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101208455; called by muse, mutect2, varscan2
- PHTF1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV63367695; called by muse, mutect2, varscan2
- PIK3IP1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV99313953; called by muse, mutect2, varscan2
- PLEKHB2 | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.852); catalogued as COSV99301560; called by muse, mutect2, varscan2
- PLXNA1 | c.5639G>A p.R1880Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs755300042, COSV52528401, COSV99302588; called by muse, mutect2, varscan2
- PRPF4B | c.2291G>A p.C764Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100528102; called by muse, mutect2, varscan2
- PTPRC | c.101-1G>A p.X34_splice | Splice Site (SNP) | VAF 33/125 reads (26%) | catalogued as rs766200564, COSV61409733; called by muse, mutect2, varscan2
- RBPJ | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV60749370; called by muse, mutect2, varscan2
- RIMS4 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV65719285, COSV65720221; called by muse, mutect2, varscan2
- RNF103 | c.1863T>G p.C621W | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99410019; called by muse, mutect2, varscan2
- RTTN | c.6063G>A p.M2021I | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55342613, COSV99731501; called by muse, mutect2, varscan2
- RXFP1 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769650864, COSV100313614, COSV100314175; called by muse, mutect2, varscan2
- SELENOO | c.1480T>C p.F494L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV99955090; called by muse, mutect2, varscan2
- SLC52A3 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748083229, COSV99447693; called by muse, mutect2, varscan2
- SNAPC4 | c.2894C>T p.T965I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as COSV100046942; called by muse, mutect2, varscan2
- SNTB1 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101179891; called by muse, mutect2, varscan2
- SOX11 | c.884A>T p.D295V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100430894; called by muse, mutect2, varscan2
- SOX9 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99818257; called by muse, mutect2, varscan2
- STAT5B | c.1964C>A p.S655Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99510767; called by muse, varscan2
- TACC3 | c.2243A>G p.K748R | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV100508575; called by muse, mutect2, varscan2
- TBCEL | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99412020; called by muse, mutect2, varscan2
- TJP1 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.37); catalogued as rs1458432600, COSV100632468; called by muse, mutect2, varscan2
- TLDC2 | c.467del p.F156Sfs*3 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | catalogued as rs1424868252; called by mutect2, pindel, varscan2
- TP53 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as CM073388, COSV52663474, COSV52761478, COSV52776039, COSV53023378; called by muse, mutect2, varscan2
- TUBD1 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs753825071, COSV100360005; called by muse, mutect2, varscan2
- TUT4 | c.2402C>G p.S801C | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99931973; called by muse, mutect2, varscan2
- UBR1 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs751115743, COSV99316805; called by muse, mutect2, varscan2
- UGT2B11 | c.169G>C p.A57P | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV101485226; called by muse, mutect2
- VPS13A | c.6982G>A p.A2328T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100652359; called by muse, mutect2, varscan2
- WARS2 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99346098; called by muse, varscan2
- XKRX | c.13T>C p.Y5H | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.165); catalogued as COSV100139593; called by muse, mutect2, varscan2
- ZDHHC8 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs954924406, COSV57709208; called by muse, mutect2, varscan2
- ZNF12 | c.1367A>G p.Y456C (on ENST00000405858 / NM_016265.4; = p.Y418C on NM_006956.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703617; called by muse, mutect2, varscan2
- ZNF595 | c.801G>C p.R267S | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.39); PolyPhen benign (0.199); catalogued as COSV100227514; called by muse, mutect2, varscan2
- BAP1 | c.799_800del p.Q267Afs*16 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by pindel, varscan2
- CD300E | c.587del p.N196Tfs*103 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1120_1122+6del p.X374_splice (on ENST00000281708 / NM_001349798.2; = p.X294_splice on NM_018315.5) | Splice Site (DEL) | VAF 53/102 reads (52%) | called by mutect2, pindel, varscan2
- SCAF4 | c.2024dup p.T676Nfs*98 | Frame Shift Ins (INS) | VAF 31/147 reads (21%) | called by mutect2, pindel, varscan2
- XRCC4 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2
- ANKZF1 | c.771C>T p.H257= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99850354; called by muse, mutect2, varscan2
- AOC1 | c.1728C>T p.Y576= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100710679; called by muse, mutect2, varscan2
- CHD3 | c.2451G>A p.T817= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV57875780; called by muse, mutect2, varscan2
- CLCF1 | c.174T>A p.A58= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV100425605; called by muse, mutect2, varscan2
- DSCAML1 | c.5331C>T p.I1777= (on ENST00000321322; = p.I1717= on NM_020693.4) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs767828414, COSV58394395; called by mutect2, varscan2
- GRK5 | c.1488C>T p.D496= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs368864312; called by muse, mutect2, varscan2
- LCOR | c.1995C>T p.P665= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV99616711; called by muse, mutect2, varscan2
- LRRC41 | c.1302A>G p.E434= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV100586177; called by muse, mutect2, varscan2
- METAP1D | c.777T>C p.H259= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100249847; called by muse, mutect2, varscan2
- MST1R | c.2871G>A p.T957= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1272579371, COSV99617246; called by muse, mutect2, varscan2
- MTHFR | c.1467C>T p.N489= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs374026519, COSV100453503; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR1L8 | c.21C>A p.T7= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100508452; called by muse, mutect2
- OR6K2 | c.636G>A p.V212= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV100656737; called by muse, mutect2, varscan2
- SH3D21 | c.1110C>T p.N370= (on ENST00000453908 / NM_001162530.2; = p.N259= on NM_024676.5) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs774541805, COSV54634312; called by muse, mutect2, varscan2
- SLCO5A1 | c.996T>C p.N332= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99479609; called by muse, mutect2
- SYNE2 | c.9963C>T p.S3321= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100647089; called by muse, mutect2, varscan2
- ZNF331 | c.384G>A p.E128= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV99466874, COSV99467018; called by muse, mutect2, varscan2
- ZNF628 | c.2727G>A p.A909= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99219855; called by muse, mutect2, varscan2
- ZNF804B | c.2493C>T p.N831= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100302524; called by muse, mutect2, varscan2
- CASP2 | c.967+94G>A | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100130922; called by muse, mutect2, varscan2
- CDH18 | c.-1A>C | 5'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99932916; called by muse, mutect2, varscan2
- MASP1 | c.1303+5570G>A | Intron (SNP) | VAF 15/89 reads (17%) | catalogued as rs774753334, COSV99961958; called by muse, mutect2, varscan2
- OBSCN | c.18662-1860C>T | Intron (SNP) | VAF 17/49 reads (35%) | catalogued as COSV52829320; called by muse, mutect2, varscan2
